Somatic mutation profile of cancer-model specimen HCM-CSHL-0807-C54-85B (3D Organoid, passage 6; aliquot HCM-CSHL-0807-C54-85B-01D-A85K-36), derived from the primary tumor of HCMI case HCM-CSHL-0807-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3.
Specimen HCM-CSHL-0807-C54-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df039763-16f7-4a79-8b8e-b82aa6ab86e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0807-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0807-C54-11A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f04e1bce-1dad-4a63-b36b-5accf5f07237

The open-access MAF lists 582 somatic variants for this specimen: 409 protein-altering or splice-affecting, 148 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 308, Silent 148, Frame Shift Del 59, Frame Shift Ins 16, Nonsense Mutation 13, Intron 12, Splice Region 6, 3'UTR 5, Splice Site 4, In Frame Del 3, 5'UTR 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 118/270 reads (44%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, varscan2
- KANSL1 | c.2935_2936del p.L979Vfs*10 (on ENST00000574590 / NM_001193465.2; = p.L980Vfs*10 on NM_015443.4) | Frame Shift Del (DEL) | VAF 269/670 reads (40%) | catalogued as rs1568366050; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 157/338 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- PTPRT | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 254/518 reads (49%) | hotspot (GDC flag); catalogued as COSV61965733, COSV62024591; called by muse, mutect2, varscan2
- SCN2A | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 195/430 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553579488, COSV51846923; ClinVar: pathogenic; called by muse, varscan2
- AARS2 | c.2872C>T p.R958* | Nonsense Mutation (SNP) | VAF 193/427 reads (45%) | catalogued as rs779332260, COSV55113292; called by muse, varscan2
- ABCD3 | c.161del p.K54Rfs*18 | Frame Shift Del (DEL) | VAF 148/275 reads (54%) | catalogued as COSV59867013; called by mutect2, varscan2
- AC008676.3 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 185/422 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56637457, COSV56638075; called by muse, mutect2, varscan2
- ADAMTS14 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 135/282 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1438720264; called by muse, mutect2, varscan2
- AHCTF1 | c.2792del p.L931Cfs*8 (on ENST00000366508; = p.L905Cfs*8 on NM_015446.5) | Frame Shift Del (DEL) | VAF 132/696 reads (19%) | catalogued as rs1558240077, COSV58245421; called by mutect2, pindel, varscan2
- ALPP | c.202del p.V68Cfs*4 | Frame Shift Del (DEL) | VAF 53/321 reads (17%) | catalogued as COSV67395673; called by mutect2, pindel, varscan2
- ANAPC2 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 148/292 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749339424, COSV60568920; called by muse, mutect2, varscan2
- ANKRD35 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 172/802 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV62909879; called by muse, mutect2, varscan2
- ARHGAP17 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 154/323 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs199829132, COSV99253057; called by muse, mutect2, varscan2
- ASIC2 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 115/313 reads (37%) | catalogued as COSV56757023; called by muse, mutect2, varscan2
- ATP7A | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58451209; called by muse, mutect2, varscan2
- ATRNL1 | c.2087G>A p.S696N | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV61817977; called by muse, mutect2, varscan2
- BATF3 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 155/995 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54658809; called by muse, mutect2, varscan2
- BEST1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 157/350 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs267606676, CM097859, CM155011, COSV57121542; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRF2 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 200/409 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs983775121, COSV55103603; called by muse, mutect2, varscan2
- BTBD18 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 173/354 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1433272019; called by muse, mutect2, varscan2
- C2CD5 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 123/240 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs371918229, COSV61724592; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 108/279 reads (39%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CAAP1 | c.143del p.G48Afs*82 | Frame Shift Del (DEL) | VAF 225/592 reads (38%) | catalogued as rs1480420306; called by mutect2, pindel, varscan2
- CACNA1B | c.108del p.L37Cfs*64 | Frame Shift Del (DEL) | VAF 179/1165 reads (15%) | catalogued as rs1474416938; called by mutect2, pindel, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 261/636 reads (41%) | catalogued as rs760298114; called by mutect2, pindel, varscan2
- CARD11 | c.1834G>A p.G612R | Missense Mutation (SNP) | VAF 189/397 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs755710637, COSV62757067; called by muse, mutect2
- CASC3 | c.1159G>C p.A387P | Missense Mutation (SNP) | VAF 230/438 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV52868362; called by muse, mutect2, varscan2
- CCDC191 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 192/404 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.308); catalogued as rs775836695, COSV55669985; called by muse, mutect2, varscan2
- CCDC92 | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 213/446 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53020137; called by muse, mutect2, varscan2
- CDC42BPG | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 214/407 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1424452327, COSV61349164; called by muse, mutect2, varscan2
- CENPE | c.7328A>G p.Q2443R | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs115120218; called by muse, mutect2, varscan2
- CHRNB2 | c.991A>G p.M331V | Missense Mutation (SNP) | VAF 208/900 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1207496178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST8 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 186/378 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs538795960, COSV52859119; called by muse, mutect2, varscan2
- CHTF18 | c.1414G>A p.G472S | Missense Mutation (SNP) | VAF 286/605 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as rs763671949, COSV50101791; called by muse, mutect2
- CIITA | c.3254C>T p.T1085M | Missense Mutation (SNP) | VAF 167/366 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752458730; called by muse, mutect2, varscan2
- CLDN22 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 213/457 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60109730; called by muse, varscan2
- CNTN3 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766479438; called by muse, varscan2
- COMMD2 | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 199/410 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1250312635; called by muse, mutect2, varscan2
- CORO1A | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 242/489 reads (49%) | SIFT tolerated (0.82); PolyPhen benign (0.242); catalogued as rs775464405, COSV99531907; called by muse, mutect2, varscan2
- CRLS1 | c.37del p.A13Pfs*103 | Frame Shift Del (DEL) | VAF 149/349 reads (43%) | catalogued as rs35036314; called by mutect2, pindel, varscan2
- CSMD3 | c.2423G>T p.R808L (on ENST00000297405 / NM_001363185.1; = p.R704L on NM_052900.3) | Missense Mutation (SNP) | VAF 164/324 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV99849520; called by mutect2, varscan2
- CUL4A | c.766G>A p.V256I (on ENST00000375440 / NM_001008895.4; = p.V156I on NM_003589.3) | Missense Mutation (SNP) | VAF 112/222 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs918993044; called by muse, mutect2
- CYFIP1 | c.3691G>A p.G1231R | Missense Mutation (SNP) | VAF 187/388 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs376649215; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 66/206 reads (32%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DHRS9 | c.669dup p.L224Tfs*21 | Frame Shift Ins (INS) | VAF 160/335 reads (48%) | catalogued as rs756920263; called by mutect2, varscan2
- DNAAF1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 207/401 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs200440212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPF3 | c.744C>A p.P248= | Splice Region (SNP) | VAF 119/279 reads (43%) | catalogued as rs767776343; called by muse, varscan2
- EDA | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 376/763 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.169); catalogued as rs757610457, CD042590; called by muse, mutect2, varscan2
- EDEM2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 154/322 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs536739541; called by muse, mutect2, varscan2
- EEF1A1 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.524); catalogued as COSV58550043; called by muse, varscan2
- EGLN2 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 113/220 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs774710749; called by muse, mutect2, varscan2
- EHD2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 270/529 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs201716618, COSV54408102; called by muse, mutect2, varscan2
- EXT2 | c.29G>A p.R10Q (on ENST00000343631; = p.R43Q on NM_000401.3) | Missense Mutation (SNP) | VAF 206/435 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); catalogued as rs146906186; called by muse, mutect2, varscan2
- FAM234B | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs766526805, COSV52195300; called by muse, mutect2, varscan2
- FAM83D | c.500T>C p.M167T | Missense Mutation (SNP) | VAF 105/260 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.506); catalogued as rs1034273002; called by muse, mutect2, varscan2
- FASN | c.7237C>T p.R2413C | Missense Mutation (SNP) | VAF 226/442 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as rs765469966; called by muse, mutect2, varscan2
- FBXW5 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 202/390 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs771667923, COSV56402422; called by muse, varscan2
- FIBCD1 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 205/472 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs777609555; called by muse, mutect2, varscan2
- FNDC5 | c.214_216del p.K72del | In Frame Del (DEL) | VAF 100/227 reads (44%) | catalogued as rs775897042; called by pindel, varscan2
- FRMD1 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 190/382 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); catalogued as rs201421071, COSV51961851; called by muse, mutect2, varscan2
- FYTTD1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 118/249 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1560497331, COSV54084803; called by muse, mutect2, varscan2
- GADL1 | c.1065del p.K355Nfs*19 | Frame Shift Del (DEL) | VAF 122/301 reads (41%) | catalogued as COSV56975277; called by mutect2, pindel, varscan2
- GLRA2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 185/407 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748764171; called by muse, mutect2, varscan2
- GRM6 | c.727dup p.V243Gfs*40 | Frame Shift Ins (INS) | VAF 93/236 reads (39%) | catalogued as rs281865186; ClinVar: not provided; called by mutect2, varscan2
- GTF3C4 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 143/289 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs528646416, COSV100935941; called by muse, mutect2, varscan2
- H2AP | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 290/613 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1393449126, COSV61911012; called by muse, mutect2, varscan2
- HCN2 | c.2167G>A p.V723I | Missense Mutation (SNP) | VAF 240/504 reads (48%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.013); catalogued as rs753793346; ClinVar: uncertain significance; called by muse, varscan2
- HELZ2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 291/564 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765466407; called by muse, mutect2, varscan2
- HERC5 | c.1812del p.F604Lfs*2 | Frame Shift Del (DEL) | VAF 175/331 reads (53%) | catalogued as rs1256699530; called by mutect2, varscan2
- HIPK3 | c.1300dup p.C434Lfs*20 | Frame Shift Ins (INS) | VAF 138/282 reads (49%) | catalogued as rs761758734; called by mutect2, varscan2
- HIVEP3 | c.7106C>T p.T2369M | Missense Mutation (SNP) | VAF 225/473 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs780755769; called by muse, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 118/278 reads (42%) | catalogued as rs748579647; called by mutect2, varscan2
- IGFN1 | c.2449C>T p.R817W (on ENST00000295591 / NM_001367841.1; = p.R3274W on NM_001164586.2) | Missense Mutation (SNP) | VAF 227/872 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs566696923; called by muse, mutect2, varscan2
- INPPL1 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV53353158; called by muse, mutect2, varscan2
- INSRR | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 295/1088 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV63871574, COSV63876415; called by muse, mutect2, varscan2
- ITGA10 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 160/853 reads (19%) | catalogued as rs782249120, COSV65196144, COSV65198308; called by mutect2, pindel, varscan2
- ITSN1 | c.2066A>G p.K689R | Missense Mutation (SNP) | VAF 61/476 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1342197848; called by muse, mutect2, varscan2
- JDP2 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 204/452 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.14); catalogued as rs1332446889; called by muse, mutect2, varscan2
- KAT2B | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV55435423; called by muse, mutect2, varscan2
- KAZN | c.73A>G p.N25D | Missense Mutation (SNP) | VAF 224/496 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs1166087320, COSV65724173; called by muse, varscan2
- KDM5B | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 176/661 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as rs61750266; called by muse, mutect2, varscan2
- KHDRBS3 | c.471T>C p.P157= | Splice Region (SNP) | VAF 124/231 reads (54%) | catalogued as rs753718103; called by muse, varscan2
- KIAA2026 | c.2187dup p.A730Sfs*15 | Frame Shift Ins (INS) | VAF 126/264 reads (48%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF2B | c.626del p.P209Rfs*10 | Frame Shift Del (DEL) | VAF 219/466 reads (47%) | catalogued as COSV52136659; called by mutect2, varscan2
- KLHDC7A | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 255/536 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV68769714; called by muse, mutect2
- KRTAP4-2 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 302/637 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs781168054; called by muse, mutect2, varscan2
- LAMA2 | c.6599G>A p.R2200H | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs779326725, COSV70351053; ClinVar: uncertain significance; called by muse, varscan2
- LGALS4 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 205/405 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772845641; called by muse, mutect2, varscan2
- LIPC | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 203/446 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs376854598; called by muse, mutect2, varscan2
- LRRC32 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 235/477 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1221005538, COSV52632730; called by muse, mutect2, varscan2
- LRRC66 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 206/428 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs527846401, COSV100602767, COSV58632301; called by muse, mutect2, varscan2
- MAST3 | c.3778C>T p.R1260* | Nonsense Mutation (SNP) | VAF 219/438 reads (50%) | catalogued as COSV53225351; called by muse, mutect2, varscan2
- MBTD1 | c.493A>G p.M165V | Missense Mutation (SNP) | VAF 8/247 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as rs1000700353; called by muse, mutect2
- MBTPS1 | c.3149C>A p.P1050H | Missense Mutation (SNP) | VAF 123/241 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58571222; called by muse, mutect2, varscan2
- MDN1 | c.4687C>T p.R1563C | Missense Mutation (SNP) | VAF 99/244 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs761391000, COSV65522570; called by muse, mutect2, varscan2
- MEAK7 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 248/470 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs146062987; called by muse, mutect2
- MFN2 | c.1658T>C p.V553A | Missense Mutation (SNP) | VAF 144/311 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV52420990; called by muse, mutect2, varscan2
- MGAM | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.238); catalogued as rs371373847; called by muse, mutect2, varscan2
- MGAT5 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 167/368 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1361689219, COSV56099225; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 185/417 reads (44%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 221/869 reads (25%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NOTCH1 | c.3905G>A p.R1302H | Missense Mutation (SNP) | VAF 196/400 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs762091081; called by muse, varscan2
- OR2M7 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 216/925 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100522605; called by muse, mutect2, varscan2
- OVOL1 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 268/509 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs1430458584; called by muse, varscan2
- PCDHGA1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 286/594 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs754685144, COSV65297868; called by muse, mutect2, varscan2
- PCDHGA2 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 392/771 reads (51%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as COSV54040233; called by muse, mutect2, varscan2
- PGBD5 | c.784C>T p.R262W (on ENST00000525115; = p.R331W on NM_001258311.2) | Missense Mutation (SNP) | VAF 208/824 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs762626765; called by muse, varscan2
- PGR | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 287/566 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as rs1380505844; called by muse, mutect2, varscan2
- PIEZO1 | c.6263G>A p.R2088H | Missense Mutation (SNP) | VAF 228/510 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs868476887, COSV99966343; called by muse, mutect2, varscan2
- PIGR | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 172/679 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as rs773272615, COSV104423532; called by muse, mutect2, varscan2
- PITPNM3 | c.2452C>T p.R818W | Missense Mutation (SNP) | VAF 206/403 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1459384243, COSV52593161; called by muse, mutect2, varscan2
- PKD1 | c.3838G>A p.A1280T | Missense Mutation (SNP) | VAF 30/618 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs779028845; called by muse, mutect2
- PNISR | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 174/334 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.069); catalogued as rs774652494; called by muse, mutect2, varscan2
- PP2D1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 185/377 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV60748222; called by muse, mutect2, varscan2
- PPOX | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 206/878 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1225937420; called by muse, mutect2, varscan2
- PREX1 | c.2620G>A p.V874M | Missense Mutation (SNP) | VAF 227/462 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs752025821; called by muse, mutect2, varscan2
- PTPRG | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 155/326 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV55637474; called by muse, mutect2, varscan2
- PUM3 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 215/467 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs142006198, COSV65896618; called by muse, mutect2
- RAI2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 311/620 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0.381); catalogued as rs954913951, COSV58963877; called by muse, mutect2, varscan2
- RERE | c.3249dup p.S1084Vfs*19 | Frame Shift Ins (INS) | VAF 268/543 reads (49%) | catalogued as rs745806637; ClinVar: uncertain significance; called by mutect2, varscan2
- RGMB | c.817G>A p.A273T (on ENST00000513185 / NM_001366508.1; = p.A314T on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 186/401 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760127625, COSV100374987, COSV57567093; called by muse, mutect2, varscan2
- RILP | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 193/404 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs1333104806; called by muse, mutect2, varscan2
- RNF208 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 225/474 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs1487917693; called by muse, varscan2
- RNF43 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 238/495 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs531889929, COSV68460140; called by muse, varscan2
- ROR1 | c.2701G>A p.V901I | Missense Mutation (SNP) | VAF 180/341 reads (53%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.105); catalogued as rs749054305; called by muse, mutect2, varscan2
- RRP1 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 163/314 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1448504124; called by muse, mutect2, varscan2
- SDK1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 31/502 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs1198312315, COSV67387443; called by muse, mutect2
- SEC14L5 | c.1863dup p.S622Qfs*31 | Frame Shift Ins (INS) | VAF 241/468 reads (51%) | catalogued as rs764657044; called by mutect2, varscan2
- SEC61A2 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs935846832; called by muse, mutect2, varscan2
- SETD2 | c.4786T>C p.Y1596H | Missense Mutation (SNP) | VAF 123/242 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100338302; called by muse, varscan2
- SEZ6L2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 279/526 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as rs1330909596, COSV100435731; called by muse, mutect2, varscan2
- SLC17A1 | c.168G>T p.L56F | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.873); catalogued as COSV55081041; called by muse, mutect2, varscan2
- SLC25A2 | c.724A>G p.M242V | Missense Mutation (SNP) | VAF 194/397 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs782492357; called by muse, mutect2, varscan2
- SLC2A5 | c.1247dup p.S417Qfs*64 | Frame Shift Ins (INS) | VAF 163/388 reads (42%) | catalogued as rs1223118492; called by mutect2, pindel, varscan2
- SMG1 | c.8098T>C p.C2700R | Missense Mutation (SNP) | VAF 136/271 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV67169522; called by muse, mutect2, varscan2
- SNAPC4 | c.4004del p.G1335Afs*72 | Frame Shift Del (DEL) | VAF 255/636 reads (40%) | catalogued as rs749900519; called by mutect2, pindel, varscan2
- SNAPC4 | c.2869G>C p.A957P | Missense Mutation (SNP) | VAF 228/446 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs575245185; called by muse, mutect2, varscan2
- SNRNP70 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 268/554 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.98); catalogued as COSV99672257; called by muse, mutect2, varscan2
- SNX14 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 191/399 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs1273920478; called by muse, mutect2, varscan2
- SPAG4 | c.1178del p.P393Qfs*7 | Frame Shift Del (DEL) | VAF 145/323 reads (45%) | catalogued as rs1292316291; called by mutect2, pindel, varscan2
- SPEM1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 167/324 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1291482484; called by muse, varscan2
- SPTBN4 | c.5566C>T p.R1856W | Missense Mutation (SNP) | VAF 239/475 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368152529; called by muse, mutect2, varscan2
- SRGAP2 | c.2599G>T p.G867W (on ENST00000624873 / NM_001170637.4; = p.G868W on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 236/987 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs1553379345, COSV55340823; called by muse, mutect2, varscan2
- SYNE3 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 206/403 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1487783424; called by muse, mutect2, varscan2
- TAF1C | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 210/458 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58985932; called by muse, mutect2, varscan2
- TAF5 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 296/616 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1447579611; called by muse, mutect2, varscan2
- TCHH | c.5513G>A p.R1838Q | Missense Mutation (SNP) | VAF 263/1034 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV64274051; called by muse, mutect2, varscan2
- TCTN1 | c.1282C>T p.R428W (on ENST00000551590 / NM_001173975.3; = p.R414W on NM_024549.6) | Missense Mutation (SNP) | VAF 198/407 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs572643772, COSV66541703; called by muse, mutect2, varscan2
- THBS2 | c.3076G>A p.G1026S | Missense Mutation (SNP) | VAF 249/465 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs749110426; called by muse, mutect2, varscan2
- THOP1 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 149/313 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1048224954; called by muse, mutect2, varscan2
- TMEM104 | c.1303T>C p.Y435H | Missense Mutation (SNP) | VAF 270/535 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343021639; called by muse, mutect2, varscan2
- TMEM245 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 162/335 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as rs755443750; called by muse, mutect2, varscan2
- TMEM72 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 201/360 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67460115; called by muse, mutect2, varscan2
- TMEM94 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 198/405 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1229354895; called by muse, mutect2, varscan2
- TRADD | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 210/472 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770547657, COSV50758337; called by muse, mutect2, varscan2
- TRAV30 | c.266del p.K89Sfs*? | Frame Shift Del (DEL) | VAF 158/346 reads (46%) | catalogued as rs373076040; called by mutect2, varscan2
- TTC27 | c.1814A>G p.Y605C | Missense Mutation (SNP) | VAF 139/274 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377057367; called by muse, mutect2, varscan2
- VCL | c.2369T>C p.L790S | Missense Mutation (SNP) | VAF 176/355 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99280627; called by muse, mutect2, varscan2
- VDAC3 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 165/376 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs764325542, COSV50081571; called by muse, mutect2, varscan2
- VPS9D1 | c.1274T>C p.L425P | Missense Mutation (SNP) | VAF 110/224 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1179409241; called by muse, mutect2, varscan2
- WDFY4 | c.2834A>T p.H945L | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV57434671; called by muse, mutect2
- WIZ | c.2613del p.S872Afs*15 (on ENST00000673675 / NM_001371589.1; = p.S135Afs*15 on NM_021241.3) | Frame Shift Del (DEL) | VAF 277/617 reads (45%) | catalogued as COSV54610544; called by mutect2, pindel, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 251/614 reads (41%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- XYLT1 | c.2287A>G p.M763V | Missense Mutation (SNP) | VAF 218/466 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.171); catalogued as rs145121977; called by muse, mutect2, varscan2
- ZBTB22 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 340/720 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99801256; called by muse, mutect2, varscan2
- ZNF124 | c.1015dup p.T339Nfs*9 (on ENST00000543802 / NM_001297568.1; = p.T277Nfs*9 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 148/634 reads (23%) | catalogued as rs746309323; called by mutect2, varscan2
- ZNF335 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 199/458 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs556571682; called by muse, mutect2, varscan2
- ZNF500 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 196/425 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs778491069; called by muse, mutect2, varscan2
- ZNF524 | c.174del p.K59Sfs*14 | Frame Shift Del (DEL) | VAF 194/424 reads (46%) | catalogued as rs750719825; called by mutect2, varscan2
- ZNF536 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 222/462 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1462410123, COSV62822885, COSV62828065; called by muse, varscan2
- ZNF687 | c.1729A>G p.S577G | Missense Mutation (SNP) | VAF 227/939 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV55020910; called by muse, mutect2, varscan2
- ZSCAN26 | c.1294C>T p.R432* (on ENST00000623276 / NM_001111039.2; = p.R298* on NM_152736.5) | Nonsense Mutation (SNP) | VAF 156/310 reads (50%) | catalogued as rs757181763; called by muse, mutect2, varscan2
- AC092143.1 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 22/338 reads (7%) | called by muse, mutect2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 96/180 reads (53%) | called by mutect2, varscan2
- ADAR | c.2185G>T p.G729C | Missense Mutation (SNP) | VAF 209/740 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRB1 | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 294/564 reads (52%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, varscan2
- AMDHD2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 252/540 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- AMER1 | c.2060C>G p.T687S | Missense Mutation (SNP) | VAF 316/612 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- ANKS1A | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 214/471 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AOC1 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 218/453 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- APEX2 | c.1090del p.R364Gfs*30 | Frame Shift Del (DEL) | VAF 300/686 reads (44%) | called by mutect2, pindel, varscan2
- AQR | c.3919G>C p.V1307L | Missense Mutation (SNP) | VAF 190/402 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ARHGEF5 | c.4735C>A p.L1579M | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ARMH3 | c.1673T>C p.M558T | Missense Mutation (SNP) | VAF 141/276 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ATRNL1 | c.1420T>C p.Y474H | Missense Mutation (SNP) | VAF 14/498 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2
- BCL11A | c.976del p.L326Sfs*61 (on ENST00000335712 / NM_001365609.1; = p.L360Sfs*61 on NM_018014.4) | Frame Shift Del (DEL) | VAF 116/338 reads (34%) | called by mutect2, pindel, varscan2
- BEX2 | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 272/639 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BNIP2 | c.456del p.V153Lfs*12 | Frame Shift Del (DEL) | VAF 103/231 reads (45%) | called by mutect2, pindel, varscan2
- BNIP3 | c.582del p.K195Rfs*16 | Frame Shift Del (DEL) | VAF 146/361 reads (40%) | called by mutect2, pindel, varscan2
- BROX | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 107/527 reads (20%) | called by muse, mutect2, varscan2
- C15orf39 | c.940G>T p.G314W | Missense Mutation (SNP) | VAF 277/551 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CACNB1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 186/354 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CAMSAP1 | c.1496T>C p.I499T | Missense Mutation (SNP) | VAF 167/364 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CASK | c.2261A>G p.H754R (on ENST00000378163 / NM_001367721.1; = p.H749R on NM_003688.3) | Missense Mutation (SNP) | VAF 169/360 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CASZ1 | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 75/118 reads (64%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, varscan2
- CCDC144A | c.1205A>G p.D402G | Missense Mutation (SNP) | VAF 155/315 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CCDC157 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- CCDC51 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 135/248 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH24 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 245/506 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CDKN1C | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 279/556 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CEP126 | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 122/289 reads (42%) | called by muse, mutect2, varscan2
- CEP192 | c.7476-1G>A p.X2492_splice | Splice Site (SNP) | VAF 108/218 reads (50%) | called by muse, varscan2
- CFAP91 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 126/264 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHADL | c.899dup p.Q301Pfs*194 | Frame Shift Ins (INS) | VAF 228/536 reads (43%) | called by mutect2, pindel, varscan2
- CHD6 | c.3772A>G p.R1258G | Missense Mutation (SNP) | VAF 142/313 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- CHRNA1 | c.1271T>A p.I424N (on ENST00000261007 / NM_001039523.3; = p.I399N on NM_000079.4) | Missense Mutation (SNP) | VAF 138/306 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by mutect2, varscan2
- COG7 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 219/467 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- COL17A1 | c.3794G>C p.G1265A | Missense Mutation (SNP) | VAF 140/310 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- COL5A1 | c.4941del p.D1648Tfs*81 | Frame Shift Del (DEL) | VAF 140/363 reads (39%) | called by mutect2, pindel, varscan2
- CRNN | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 230/947 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSRNP2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 171/364 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, varscan2
- CTCF | c.1430A>T p.H477L | Missense Mutation (SNP) | VAF 193/394 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, varscan2
- CYSLTR1 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 27/612 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DEPDC5 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 240/478 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- DHX34 | c.1018-1G>T p.X340_splice | Splice Site (SNP) | VAF 138/260 reads (53%) | called by muse, mutect2, varscan2
- DNAH10 | c.3417del p.E1140Rfs*42 (on ENST00000409039; = p.E1079Rfs*42 on NM_207437.3) | Frame Shift Del (DEL) | VAF 96/272 reads (35%) | called by mutect2, pindel, varscan2
- DNAH10 | c.4246del p.T1416Rfs*7 (on ENST00000409039; = p.T1355Rfs*7 on NM_207437.3) | Frame Shift Del (DEL) | VAF 186/425 reads (44%) | called by mutect2, pindel, varscan2
- DNAH14 | c.8749A>G p.T2917A (on ENST00000445597; = p.T3720A on NM_001367479.1) | Missense Mutation (SNP) | VAF 218/795 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH17 | c.10141T>A p.F3381I | Missense Mutation (SNP) | VAF 126/283 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DNAH17 | c.7046T>C p.L2349P | Missense Mutation (SNP) | VAF 26/551 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DNMBP | c.887T>C p.F296S | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DOC2B | c.765+1G>A p.X255_splice | Splice Site (SNP) | VAF 150/279 reads (54%) | called by muse, mutect2, varscan2
- DOCK8 | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 122/276 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPT | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 191/697 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DUSP9 | c.714del p.N239Tfs*197 | Frame Shift Del (DEL) | VAF 276/698 reads (40%) | called by mutect2, pindel, varscan2
- DYRK1B | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 293/633 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- E2F1 | c.452T>A p.V151D | Missense Mutation (SNP) | VAF 168/352 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- E2F1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 210/405 reads (52%) | called by muse, mutect2, varscan2
- EIF1AD | c.169T>C p.Y57H | Missense Mutation (SNP) | VAF 10/314 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- EIF2B5 | c.2018A>G p.K673R (on ENST00000647909; = p.K665R on NM_003907.3) | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ELF1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 168/324 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.127); called by muse, mutect2
- ELP1 | c.3756_3759del p.R1253Nfs*12 | Frame Shift Del (DEL) | VAF 130/318 reads (41%) | called by pindel, varscan2
- ENTPD6 | c.139del p.L47Wfs*84 | Frame Shift Del (DEL) | VAF 196/479 reads (41%) | called by mutect2, pindel, varscan2
- EP300 | c.4736A>G p.D1579G | Missense Mutation (SNP) | VAF 191/377 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F10 | c.659T>A p.F220Y | Missense Mutation (SNP) | VAF 23/619 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.222); called by muse, mutect2
- F2RL2 | c.349T>C p.W117R | Missense Mutation (SNP) | VAF 226/446 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, varscan2
- FAHD2A | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 114/254 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM186B | c.1214T>C p.F405S | Missense Mutation (SNP) | VAF 191/392 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FBN3 | c.5671A>G p.T1891A | Missense Mutation (SNP) | VAF 111/205 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FCRLB | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 182/706 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FOXN4 | c.598T>C p.C200R | Missense Mutation (SNP) | VAF 134/325 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FPR1 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 174/398 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- FZD8 | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 225/455 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAB4 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 218/452 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- GATA6 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 194/412 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, varscan2
- GATAD2A | c.1850T>A p.L617H | Missense Mutation (SNP) | VAF 16/468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GCSAML | c.316T>G p.S106A | Missense Mutation (SNP) | VAF 219/883 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GDPD3 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 165/365 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GEN1 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, varscan2
- GHITM | c.712A>C p.S238R | Missense Mutation (SNP) | VAF 190/374 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- GRAMD1B | c.405G>T p.W135C | Missense Mutation (SNP) | VAF 178/323 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN2B | c.3926A>G p.D1309G | Missense Mutation (SNP) | VAF 213/448 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GRK5 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 208/415 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSN | c.1186T>C p.W396R | Missense Mutation (SNP) | VAF 140/301 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF2I | c.1952C>T p.S651F (on ENST00000573035 / NM_032999.4; = p.S610F on NM_001518.5) | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- HAUS3 | c.713T>C p.F238S | Missense Mutation (SNP) | VAF 154/336 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- HMCN1 | c.9490A>G p.T3164A | Missense Mutation (SNP) | VAF 95/485 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, varscan2
- HNRNPD | c.555dup p.V186Cfs*10 | Frame Shift Ins (INS) | VAF 193/480 reads (40%) | called by mutect2, pindel, varscan2
- HOXA10 | c.156_161del p.G55_G56del | In Frame Del (DEL) | VAF 272/562 reads (48%) | called by mutect2, pindel, varscan2
- HSPA12B | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 263/572 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- IARS2 | c.1493dup p.V499Gfs*14 | Frame Shift Ins (INS) | VAF 139/606 reads (23%) | called by mutect2, pindel, varscan2
- IBA57 | c.632del p.G211Afs*40 | Frame Shift Del (DEL) | VAF 215/985 reads (22%) | called by mutect2, pindel, varscan2
- ICE1 | c.4054G>A p.A1352T | Missense Mutation (SNP) | VAF 196/357 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- IFI6 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 251/525 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- IFIT5 | c.192del p.G65Afs*16 | Frame Shift Del (DEL) | VAF 132/288 reads (46%) | called by mutect2, varscan2
- IGF2R | c.6310G>A p.A2104T | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- IHO1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 191/373 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- INPPL1 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 235/433 reads (54%) | called by muse, mutect2, varscan2
- INPPL1 | c.1981T>C p.Y661H | Missense Mutation (SNP) | VAF 132/297 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- INSRR | c.820T>G p.C274G | Missense Mutation (SNP) | VAF 203/888 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- INTS6 | c.560C>A p.T187K | Missense Mutation (SNP) | VAF 136/273 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- IP6K1 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ITM2A | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 162/323 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- KATNAL2 | c.105T>A p.H35Q | Missense Mutation (SNP) | VAF 146/321 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KCNA5 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 246/535 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KCNV1 | c.1312T>G p.L438V | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KLHDC3 | c.977A>G p.H326R | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); called by muse, mutect2
- KMT2D | c.2993dup p.M999Yfs*69 | Frame Shift Ins (INS) | VAF 187/491 reads (38%) | called by mutect2, pindel, varscan2
- KRTAP1-5 | c.70T>C p.C24R | Missense Mutation (SNP) | VAF 202/520 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- KRTAP5-1 | c.245del p.C82Lfs*? | Frame Shift Del (DEL) | VAF 95/202 reads (47%) | called by mutect2, pindel, varscan2
- KRTAP5-4 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by muse, mutect2
- LAPTM4A | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 31/327 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2
- LCOR | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 159/329 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LEFTY2 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 339/1208 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LOX | c.1199T>G p.I400S | Missense Mutation (SNP) | VAF 135/304 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- LRRC43 | c.1381T>C p.W461R | Missense Mutation (SNP) | VAF 152/354 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LUC7L2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, varscan2
- LYZL6 | c.366del p.M123* | Frame Shift Del (DEL) | VAF 156/389 reads (40%) | called by mutect2, pindel, varscan2
- LZTS3 | c.1527A>T p.E509D (on ENST00000329152; = p.E463D on NM_001282533.2) | Missense Mutation (SNP) | VAF 224/498 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAGEA11 | c.751A>G p.S251G | Missense Mutation (SNP) | VAF 241/502 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAN2A1 | c.960del p.K320Nfs*29 | Frame Shift Del (DEL) | VAF 163/421 reads (39%) | called by mutect2, pindel, varscan2
- MAPKAPK5 | c.154del p.I52Ffs*16 | Frame Shift Del (DEL) | VAF 146/360 reads (41%) | called by mutect2, pindel, varscan2
- MATN2 | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 177/369 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEAK7 | c.1342G>T p.G448W | Missense Mutation (SNP) | VAF 166/349 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED12 | c.5884A>G p.T1962A | Missense Mutation (SNP) | VAF 261/567 reads (46%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED23 | c.1460G>T p.C487F | Missense Mutation (SNP) | VAF 157/325 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MFNG | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 202/410 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- MICU3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 107/226 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPEG1 | c.1125C>A p.N375K | Missense Mutation (SNP) | VAF 218/447 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MPLKIP | c.227dup p.R77Pfs*52 | Frame Shift Ins (INS) | VAF 271/623 reads (43%) | called by mutect2, pindel, varscan2
- MPP2 | c.401T>C p.V134A (on ENST00000461854 / NM_001278372.2; = p.V110A on NM_005374.5) | Missense Mutation (SNP) | VAF 151/334 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2
- MRGBP | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 181/342 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MTHFR | c.935G>A p.S312N | Missense Mutation (SNP) | VAF 164/328 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, varscan2
- MTUS1 | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 159/373 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MVB12B | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 174/328 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MYH7B | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 209/455 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAALADL2 | c.1733A>T p.D578V | Missense Mutation (SNP) | VAF 95/372 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- NKX1-1 | c.725A>G p.D242G | Missense Mutation (SNP) | VAF 314/697 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); called by muse, mutect2
- NLRC3 | c.2567A>G p.H856R | Missense Mutation (SNP) | VAF 29/307 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRBP2 | c.509del p.P170Qfs*7 | Frame Shift Del (DEL) | VAF 158/381 reads (41%) | called by mutect2, pindel, varscan2
- NRF1 | c.1406_1412del p.G469Dfs*10 | Frame Shift Del (DEL) | VAF 176/440 reads (40%) | called by mutect2, pindel, varscan2
- NUTM1 | c.2503C>G p.L835V | Missense Mutation (SNP) | VAF 217/469 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- OTOG | c.7129T>G p.S2377A | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.451); called by muse, mutect2
- P2RX5 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 168/360 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PAOX | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 205/495 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- PAPPA2 | c.1183del p.L395* | Frame Shift Del (DEL) | VAF 221/990 reads (22%) | called by mutect2, pindel, varscan2
- PCLO | c.7906G>T p.E2636* | Nonsense Mutation (SNP) | VAF 127/290 reads (44%) | called by muse, varscan2
- PELO | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 189/367 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGBD2 | c.194A>G p.Q65R | Missense Mutation (SNP) | VAF 210/806 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF2 | c.761del p.G254Afs*87 | Frame Shift Del (DEL) | VAF 147/392 reads (38%) | called by mutect2, pindel, varscan2
- PHF21A | c.1975A>G p.T659A (on ENST00000418153 / NM_001101802.3; = p.T613A on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 205/447 reads (46%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PINK1 | c.396del p.F132Lfs*26 | Frame Shift Del (DEL) | VAF 119/316 reads (38%) | called by mutect2, pindel, varscan2
- PJA2 | c.764A>G p.E255G | Missense Mutation (SNP) | VAF 168/347 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD2 | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 107/221 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCB2 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 192/399 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PLEKHA3 | c.861del p.K287Nfs*24 | Frame Shift Del (DEL) | VAF 119/312 reads (38%) | called by mutect2, pindel, varscan2
- PLIN4 | c.3412C>G p.L1138V (on ENST00000301286; = p.L1153V on NM_001367868.2) | Missense Mutation (SNP) | VAF 242/481 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- POLI | c.16del p.V6Wfs*50 | Frame Shift Del (DEL) | VAF 202/411 reads (49%) | called by mutect2, pindel, varscan2
- PPP1R12A | c.1619dup p.N540Kfs*2 | Frame Shift Ins (INS) | VAF 86/174 reads (49%) | called by mutect2, varscan2
- PRDM7 | c.886A>G p.T296A | Missense Mutation (SNP) | VAF 115/277 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PROB1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 273/563 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PROS1 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 159/349 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRSS56 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 302/577 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTBP2 | c.1488del p.Q497Kfs*21 (on ENST00000426398 / NM_001300986.2; = p.Q489Kfs*20 on NM_021190.4) | Frame Shift Del (DEL) | VAF 102/256 reads (40%) | called by mutect2, pindel, varscan2
- PTPDC1 | c.2188A>G p.T730A (on ENST00000375360 / NM_177995.3; = p.T782A on NM_152422.4) | Missense Mutation (SNP) | VAF 130/302 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PTPN14 | c.972G>C p.W324C | Missense Mutation (SNP) | VAF 139/599 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); called by muse, mutect2
- PXDN | c.2141T>C p.L714P | Missense Mutation (SNP) | VAF 164/310 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASL10A | c.219G>T p.E73D | Missense Mutation (SNP) | VAF 176/322 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- RASSF10 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 238/531 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RGMB | c.1186G>A p.E396K (on ENST00000513185 / NM_001366508.1; = p.E437K on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 212/426 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RPGR | c.2789G>A p.S930N (on ENST00000339363 / NM_001367249.1; = p.S725N on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 163/313 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPL3L | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 132/294 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- RPP25 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 208/448 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- RRN3 | c.1637_1671del p.G546Dfs*6 | Frame Shift Del (DEL) | VAF 65/385 reads (17%) | called by mutect2, pindel, varscan2
- RTL1 | c.827A>G p.E276G | Missense Mutation (SNP) | VAF 178/392 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SAMD1 | c.926del p.G309Efs*50 | Frame Shift Del (DEL) | VAF 142/295 reads (48%) | called by mutect2, varscan2
- SCN3A | c.3739T>C p.F1247L | Missense Mutation (SNP) | VAF 189/411 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SELENOS | c.213A>G p.E71= | Splice Region (SNP) | VAF 111/225 reads (49%) | called by muse, mutect2, varscan2
- SHROOM1 | c.1944G>T p.Q648H | Missense Mutation (SNP) | VAF 156/319 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SLC23A3 | c.1283T>C p.L428P (on ENST00000409878 / NM_001144889.2; = p.L311P on NM_144712.5) | Missense Mutation (SNP) | VAF 120/258 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC25A13 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 172/381 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC49A4 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SLC9A3R1 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 215/445 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, varscan2
- SLC9A3R1 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 245/485 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.379); called by muse, varscan2
- SLC9A5 | c.654G>A p.V218= | Splice Region (SNP) | VAF 110/211 reads (52%) | called by muse, mutect2, varscan2
- SMARCA4 | c.885del p.T296Rfs*7 | Frame Shift Del (DEL) | VAF 203/418 reads (49%) | called by mutect2, varscan2
- SNX2 | c.1162_1163del p.M388Vfs*6 | Frame Shift Del (DEL) | VAF 121/354 reads (34%) | called by pindel, varscan2
- SOX9 | c.1049del p.P350Hfs*33 | Frame Shift Del (DEL) | VAF 265/657 reads (40%) | called by mutect2, pindel, varscan2
- SP9 | c.879del p.S294Afs*56 | Frame Shift Del (DEL) | VAF 184/438 reads (42%) | called by mutect2, pindel, varscan2
- SPATA12 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 219/463 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- SRCAP | c.6185T>C p.V2062A | Missense Mutation (SNP) | VAF 170/383 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SRRM2 | c.3983G>T p.G1328V | Missense Mutation (SNP) | VAF 129/264 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- SVEP1 | c.3264del p.C1089Vfs*8 | Frame Shift Del (DEL) | VAF 155/394 reads (39%) | called by mutect2, pindel, varscan2
- SYNGR2 | c.271T>C p.Y91H | Missense Mutation (SNP) | VAF 196/397 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TACC2 | c.5464_5465del p.X1822_splice | Splice Site (DEL) | VAF 97/250 reads (39%) | called by pindel, varscan2
- TBC1D9 | c.393_401del p.D131_K133del | In Frame Del (DEL) | VAF 100/264 reads (38%) | called by mutect2, pindel, varscan2
- TENM4 | c.3095C>T p.A1032V | Missense Mutation (SNP) | VAF 164/328 reads (50%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TFAP2C | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 264/497 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- THBS2 | c.626T>C p.V209A | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- TLX2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 210/430 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TMEM121 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 270/514 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TMEM35A | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 317/657 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMTC2 | c.259T>C p.Y87H | Missense Mutation (SNP) | VAF 253/532 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TNRC6A | c.3665T>C p.V1222A | Missense Mutation (SNP) | VAF 115/267 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TP53BP2 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 21/838 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRIM17 | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 218/892 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.23); called by muse, varscan2
- TRIM3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 158/329 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIO | c.3299C>G p.T1100R | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, varscan2
- TRIOBP | c.5617G>T p.G1873C (on ENST00000644935 / NM_001039141.3; = p.G160C on NM_007032.5) | Missense Mutation (SNP) | VAF 154/316 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIP6 | c.179dup p.P61Tfs*64 | Frame Shift Ins (INS) | VAF 211/535 reads (39%) | called by mutect2, pindel, varscan2
- TRPS1 | c.429del p.S144Qfs*34 (on ENST00000220888 / NM_001330599.2; = p.S157Qfs*34 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 171/431 reads (40%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 215/454 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSKS | c.992G>T p.R331M | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TTLL4 | c.3471C>A p.D1157E | Missense Mutation (SNP) | VAF 257/519 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUBAL3 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 186/390 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- TXNDC12 | c.329del p.G110Vfs*42 | Frame Shift Del (DEL) | VAF 134/356 reads (38%) | called by mutect2, pindel, varscan2
- TYW3 | c.539A>G p.E180G | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2
- UBE2O | c.227T>C p.F76S | Missense Mutation (SNP) | VAF 262/616 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- UCHL5 | c.372T>G p.A124= | Splice Region (SNP) | VAF 77/346 reads (22%) | called by muse, mutect2, varscan2
- UFSP1 | c.170del p.G57Vfs*23 | Frame Shift Del (DEL) | VAF 223/528 reads (42%) | called by mutect2, pindel, varscan2
- USP11 | c.1378G>T p.G460C (on ENST00000218348; = p.G417C on NM_001371072.1) | Missense Mutation (SNP) | VAF 347/698 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP45 | c.345T>A p.C115* | Nonsense Mutation (SNP) | VAF 138/322 reads (43%) | called by muse, mutect2
- VPS8 | c.1361C>T p.S454L (on ENST00000625842 / NM_001349294.1; = p.S452L on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/334 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- WDFY4 | c.2584A>G p.S862G | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, varscan2
- WDFY4 | c.7064T>C p.L2355P | Missense Mutation (SNP) | VAF 174/358 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDR36 | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 121/268 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- WDR4 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- WRN | c.3742G>A p.A1248T | Missense Mutation (SNP) | VAF 123/265 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- XAB2 | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 209/440 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- XPR1 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 197/815 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZCCHC2 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 194/407 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZFHX3 | c.530_555del p.A177Vfs*24 | Frame Shift Del (DEL) | VAF 179/476 reads (38%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.1135T>C p.F379L | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZMYM4 | c.2262A>G p.E754= | Splice Region (SNP) | VAF 65/134 reads (49%) | called by muse, mutect2, varscan2
- ZNF239 | c.260A>C p.Q87P | Missense Mutation (SNP) | VAF 224/505 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ZNF263 | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 176/368 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.036); called by muse, varscan2
- ZNF676 | c.180dup p.E61Rfs*9 (on ENST00000650058; = p.E29Rfs*9 on NM_001001411.3) | Frame Shift Ins (INS) | VAF 113/281 reads (40%) | called by mutect2, pindel, varscan2
- ZNRF3 | c.1936C>T p.P646S (on ENST00000544604 / NM_001206998.2; = p.P546S on NM_032173.3) | Missense Mutation (SNP) | VAF 276/539 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ABR | c.1938T>C p.G646= (on ENST00000302538 / NM_021962.5; = p.G609= on NM_001092.5) | Silent (SNP) | VAF 185/416 reads (44%) | called by muse, mutect2, varscan2
- ACCS | c.1293C>G p.L431= | Silent (SNP) | VAF 160/352 reads (45%) | called by muse, varscan2
- ACO2 | c.261G>A p.S87= | Silent (SNP) | VAF 228/456 reads (50%) | catalogued as rs748850283; called by muse, mutect2, varscan2
- ADAMTS14 | c.3258C>T p.H1086= | Silent (SNP) | VAF 256/502 reads (51%) | called by muse, mutect2
- ADAMTS16 | c.301C>T p.L101= | Silent (SNP) | VAF 142/338 reads (42%) | called by muse, varscan2
- ADAMTS4 | c.2310A>G p.T770= | Silent (SNP) | VAF 195/796 reads (24%) | called by muse, varscan2
- ADPRHL1 | c.36C>T p.S12= | Silent (SNP) | VAF 153/343 reads (45%) | catalogued as rs1292713643; called by muse, mutect2, varscan2
- ALPK3 | c.4023C>T p.C1341= | Silent (SNP) | VAF 288/567 reads (51%) | catalogued as rs745724880; called by muse, mutect2, varscan2
- AQP8 | c.219G>A p.G73= | Silent (SNP) | VAF 137/313 reads (44%) | catalogued as COSV99564145; called by muse, mutect2, varscan2
- ARHGAP30 | c.3228T>C p.P1076= (on ENST00000368013 / NM_001025598.2; = p.P865= on NM_181720.3) | Silent (SNP) | VAF 152/636 reads (24%) | called by muse, mutect2, varscan2
- ARRDC5 | c.495A>G p.P165= (on ENST00000381781; = p.P151= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 94/218 reads (43%) | called by muse, mutect2, varscan2
- ATP7B | c.897A>G p.V299= | Silent (SNP) | VAF 14/495 reads (3%) | called by muse, mutect2
- AWAT2 | c.204C>T p.R68= | Silent (SNP) | VAF 193/424 reads (46%) | called by muse, mutect2, varscan2
- C1QTNF2 | c.984C>T p.N328= (on ENST00000393975; = p.N283= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 146/275 reads (53%) | catalogued as rs773134321, COSV101220864; called by muse, mutect2, varscan2
- C8orf48 | c.678A>G p.L226= | Silent (SNP) | VAF 176/333 reads (53%) | called by muse, mutect2, varscan2
- CAPN15 | c.2436C>T p.P812= | Silent (SNP) | VAF 329/654 reads (50%) | catalogued as rs553459831; called by muse, mutect2, varscan2
- CAPZA2 | c.711T>C p.N237= | Silent (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- CBLL2 | c.264C>T p.V88= | Silent (SNP) | VAF 227/529 reads (43%) | catalogued as rs1160520299, COSV60369924; called by muse, mutect2, varscan2
- CCDC96 | c.1206T>C p.G402= | Silent (SNP) | VAF 199/433 reads (46%) | called by muse, mutect2, varscan2
- CCR10 | c.72T>C p.A24= | Silent (SNP) | VAF 188/423 reads (44%) | called by muse, mutect2, varscan2
- CDH10 | c.2286C>T p.Y762= | Silent (SNP) | VAF 185/366 reads (51%) | catalogued as rs775096429, COSV52580162; called by muse, mutect2, varscan2
- CDIP1 | c.624C>T p.C208= | Silent (SNP) | VAF 169/331 reads (51%) | called by muse, mutect2, varscan2
- CDKL5 | c.1068T>C p.A356= | Silent (SNP) | VAF 302/561 reads (54%) | called by muse, mutect2, varscan2
- CHD3 | c.4581C>T p.R1527= | Silent (SNP) | VAF 235/463 reads (51%) | catalogued as rs369890808; called by muse, mutect2, varscan2
- CLASRP | c.1638G>A p.A546= | Silent (SNP) | VAF 230/471 reads (49%) | catalogued as rs377491505; called by muse, mutect2, varscan2
- CLIC6 | c.1824T>C p.N608= (on ENST00000360731 / NM_001317009.2; = p.N590= on NM_053277.3) | Silent (SNP) | VAF 173/355 reads (49%) | called by muse, mutect2, varscan2
- CLIP2 | c.264C>T p.N88= | Silent (SNP) | VAF 240/512 reads (47%) | catalogued as rs554341269, COSV56282215; called by muse, varscan2
- CNTN2 | c.1053C>A p.A351= | Silent (SNP) | VAF 207/855 reads (24%) | called by muse, mutect2, varscan2
- CPPED1 | c.807C>T p.C269= | Silent (SNP) | VAF 236/474 reads (50%) | called by muse, mutect2, varscan2
- CREB3L4 | c.474G>A p.L158= | Silent (SNP) | VAF 122/565 reads (22%) | catalogued as rs1279033499; called by muse, varscan2
- CREBBP | c.1089T>C p.H363= | Silent (SNP) | VAF 162/312 reads (52%) | catalogued as rs969407052; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRTC1 | c.1623C>T p.H541= | Silent (SNP) | VAF 219/446 reads (49%) | catalogued as rs985853392; called by muse, varscan2
- CTDSP1 | c.189T>C p.L63= | Silent (SNP) | VAF 23/525 reads (4%) | called by muse, mutect2
- CYB561 | c.423C>T p.S141= | Silent (SNP) | VAF 131/274 reads (48%) | catalogued as rs778145290; called by muse, mutect2, varscan2
- DCTN6 | c.216T>C p.P72= | Silent (SNP) | VAF 105/236 reads (44%) | called by muse, mutect2, varscan2
- DDX20 | c.406T>C p.L136= | Silent (SNP) | VAF 101/244 reads (41%) | called by muse, varscan2
- DEGS1 | c.255T>C p.T85= | Silent (SNP) | VAF 172/718 reads (24%) | called by muse, varscan2
- DES | c.999C>T p.C333= | Silent (SNP) | VAF 138/268 reads (51%) | catalogued as rs1157722667, COSV64660988, COSV64661225; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- DHFR2 | c.441G>A p.T147= | Silent (SNP) | VAF 229/488 reads (47%) | catalogued as rs764442697, COSV58936323; called by muse, mutect2
- DKKL1 | c.633C>T p.D211= | Silent (SNP) | VAF 212/466 reads (45%) | catalogued as rs763530004; called by muse, varscan2
- DNAH17 | c.2061T>C p.Y687= | Silent (SNP) | VAF 161/308 reads (52%) | catalogued as rs771832526; called by muse, mutect2, varscan2
- DZIP3 | c.3495C>T p.C1165= | Silent (SNP) | VAF 120/298 reads (40%) | catalogued as rs200425501; called by muse, mutect2, varscan2
- EDA2R | c.231T>C p.A77= | Silent (SNP) | VAF 224/480 reads (47%) | catalogued as rs1208633844; called by muse, mutect2, varscan2
- EIF4G3 | c.525G>A p.T175= | Silent (SNP) | VAF 96/219 reads (44%) | catalogued as rs1397104329; called by muse, mutect2, varscan2
- EMC3 | c.54A>G p.L18= | Silent (SNP) | VAF 159/397 reads (40%) | catalogued as rs754615470; called by muse, mutect2, varscan2
- EMILIN1 | c.43C>T p.L15= | Silent (SNP) | VAF 208/458 reads (45%) | catalogued as rs1308006142; called by muse, mutect2, varscan2
- EPRS1 | c.4185T>C p.N1395= | Silent (SNP) | VAF 197/826 reads (24%) | called by muse, mutect2, varscan2
- ETS2 | c.1065C>T p.A355= | Silent (SNP) | VAF 126/231 reads (55%) | catalogued as rs745562769; called by muse, varscan2
- FAT1 | c.7365C>T p.H2455= | Silent (SNP) | VAF 190/406 reads (47%) | catalogued as rs746365351; called by muse, mutect2, varscan2
- FAXDC2 | c.537G>A p.T179= | Silent (SNP) | VAF 150/292 reads (51%) | catalogued as rs759823090; called by muse, mutect2, varscan2
- FBXO21 | c.955C>T p.L319= | Silent (SNP) | VAF 138/304 reads (45%) | called by muse, varscan2
- FGFR1OP2 | c.159T>C p.L53= | Silent (SNP) | VAF 72/164 reads (44%) | called by muse, mutect2, varscan2
- FMN1 | c.3681C>T p.Y1227= (on ENST00000616417 / NM_001277313.2; = p.Y1004= on NM_001103184.4) | Silent (SNP) | VAF 130/299 reads (43%) | catalogued as rs201891354, COSV57926433; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMNL1 | c.3063G>A p.P1021= | Silent (SNP) | VAF 124/264 reads (47%) | catalogued as rs764125862, COSV100057021; called by muse, mutect2, varscan2
- FOXF1 | c.918G>A p.T306= | Silent (SNP) | VAF 233/515 reads (45%) | called by muse, mutect2, varscan2
- FXR2 | c.111T>C p.S37= | Silent (SNP) | VAF 124/301 reads (41%) | called by muse, mutect2, varscan2
- FXYD7 | c.57C>T p.Y19= | Silent (SNP) | VAF 107/237 reads (45%) | called by muse, varscan2
- FZD2 | c.549G>A p.P183= | Silent (SNP) | VAF 136/303 reads (45%) | called by muse, mutect2, varscan2
- GCNT4 | c.846A>G p.P282= | Silent (SNP) | VAF 203/415 reads (49%) | catalogued as rs755169300; called by muse, mutect2, varscan2
- GGPS1 | c.615T>C p.C205= | Silent (SNP) | VAF 182/860 reads (21%) | catalogued as rs772423462; called by muse, mutect2, varscan2
- GJA4 | c.489T>C p.S163= | Silent (SNP) | VAF 200/420 reads (48%) | catalogued as rs1262810679; called by muse, varscan2
- GNRHR | c.786G>A p.R262= | Silent (SNP) | VAF 11/342 reads (3%) | called by muse, mutect2
- GPIHBP1 | c.42C>T p.F14= | Silent (SNP) | VAF 137/278 reads (49%) | catalogued as rs749010241; called by muse, mutect2, varscan2
- GRIN2D | c.2394C>T p.R798= | Silent (SNP) | VAF 218/421 reads (52%) | called by muse, varscan2
- HKDC1 | c.96C>T p.S32= | Silent (SNP) | VAF 110/265 reads (42%) | catalogued as rs768438980; called by muse, mutect2, varscan2
- HTATSF1 | c.2256C>T p.D752= | Silent (SNP) | VAF 146/311 reads (47%) | catalogued as rs34882252; called by mutect2, varscan2
- INTS6L | c.1431A>G p.T477= | Silent (SNP) | VAF 222/448 reads (50%) | called by muse, mutect2, varscan2
- ITGA7 | c.1071G>A p.G357= (on ENST00000555728; = p.G313= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 172/388 reads (44%) | called by muse, varscan2
- JARID2 | c.1635C>T p.G545= | Silent (SNP) | VAF 263/538 reads (49%) | catalogued as rs777889447, COSV59190266; called by muse, varscan2
- KCNT2 | c.1809T>C p.D603= | Silent (SNP) | VAF 150/671 reads (22%) | catalogued as rs1326959563; called by muse, mutect2, varscan2
- KCNT2 | c.1380A>G p.L460= | Silent (SNP) | VAF 122/548 reads (22%) | catalogued as rs1256248475; called by muse, mutect2, varscan2
- KCP | c.3429C>T p.R1143= (on ENST00000620378; = p.R1267= on NM_001366122.1) | Silent (SNP) | VAF 210/416 reads (50%) | called by muse, varscan2
- KDM7A | c.2626C>T p.L876= | Silent (SNP) | VAF 223/467 reads (48%) | called by muse, mutect2, varscan2
- KIAA1210 | c.1524T>C p.Y508= | Silent (SNP) | VAF 185/398 reads (46%) | called by muse, mutect2, varscan2
- KMO | c.915A>G p.A305= | Silent (SNP) | VAF 136/614 reads (22%) | catalogued as rs768734269; called by muse, mutect2, varscan2
- LAMA3 | c.4719C>T p.N1573= | Silent (SNP) | VAF 145/340 reads (43%) | called by muse, mutect2, varscan2
- LCAT | c.21A>G p.P7= | Silent (SNP) | VAF 201/420 reads (48%) | catalogued as rs1053464889, COSV50454740; called by muse, mutect2, varscan2
- LEO1 | c.1890T>C p.S630= | Silent (SNP) | VAF 125/271 reads (46%) | catalogued as rs138808664; called by muse, mutect2, varscan2
- LMTK3 | c.3198C>T p.N1066= | Silent (SNP) | VAF 316/626 reads (50%) | catalogued as rs766916333; called by muse, mutect2, varscan2
- LNX2 | c.597A>G p.T199= | Silent (SNP) | VAF 208/478 reads (44%) | catalogued as rs768422499; called by muse, mutect2
- LRRC37A3 | c.3036T>C p.T1012= | Silent (SNP) | VAF 109/237 reads (46%) | called by muse, mutect2, varscan2
- MATN3 | c.180G>A p.A60= | Silent (SNP) | VAF 193/424 reads (46%) | called by muse, mutect2, varscan2
- MCCC2 | c.1119C>T p.N373= | Silent (SNP) | VAF 152/316 reads (48%) | catalogued as rs766440020; called by muse, mutect2, varscan2
- MDH2 | c.333C>T p.D111= | Silent (SNP) | VAF 150/327 reads (46%) | catalogued as rs529395182; called by muse, varscan2
- MFHAS1 | c.903C>T p.L301= | Silent (SNP) | VAF 180/405 reads (44%) | called by muse, mutect2, varscan2
- MGA | c.3501A>G p.V1167= | Silent (SNP) | VAF 162/342 reads (47%) | called by muse, mutect2, varscan2
- MMP15 | c.921C>T p.D307= | Silent (SNP) | VAF 199/437 reads (46%) | catalogued as rs771141615; called by muse, mutect2, varscan2
- MORC4 | c.1737C>T p.L579= | Silent (SNP) | VAF 222/459 reads (48%) | called by muse, mutect2, varscan2
- MYH7B | c.438C>A p.R146= | Silent (SNP) | VAF 195/373 reads (52%) | called by muse, mutect2, varscan2
- MYO18A | c.3291C>T p.R1097= | Silent (SNP) | VAF 185/379 reads (49%) | catalogued as rs997767094, COSV100572853; called by muse, mutect2, varscan2
- MYO3A | c.4566A>G p.K1522= | Silent (SNP) | VAF 102/260 reads (39%) | called by muse, mutect2, varscan2
- NCK2 | c.708A>G p.K236= | Silent (SNP) | VAF 181/423 reads (43%) | called by muse, mutect2, varscan2
- NEURL1 | c.1305C>T p.G435= | Silent (SNP) | VAF 183/363 reads (50%) | called by muse, mutect2, varscan2
- NEURL3 | c.39G>A p.A13= | Silent (SNP) | VAF 188/386 reads (49%) | catalogued as rs756825819; called by muse, mutect2, varscan2
- NGEF | c.1857C>T p.C619= | Silent (SNP) | VAF 189/342 reads (55%) | catalogued as rs771518876, COSV99888504; called by muse, mutect2, varscan2
- NINL | c.2001C>T p.R667= | Silent (SNP) | VAF 248/515 reads (48%) | catalogued as rs751930908; called by muse, mutect2, varscan2
- NYNRIN | c.651T>C p.D217= | Silent (SNP) | VAF 247/462 reads (53%) | catalogued as rs1274837611; called by muse, mutect2, varscan2
- OFD1 | c.2349C>A p.S783= | Silent (SNP) | VAF 194/399 reads (49%) | catalogued as CD060636, COSV100407019; called by muse, mutect2, varscan2
- OGT | c.228C>T p.H76= | Silent (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- OR2G3 | c.612T>C p.V204= | Silent (SNP) | VAF 189/832 reads (23%) | called by muse, mutect2, varscan2
- OR51D1 | c.600G>A p.L200= | Silent (SNP) | VAF 235/470 reads (50%) | catalogued as COSV62914780; called by muse, mutect2, varscan2
- OR56A1 | c.402G>A p.R134= | Silent (SNP) | VAF 154/316 reads (49%) | catalogued as COSV57362244; called by muse, varscan2
- PAK1IP1 | c.447G>A p.T149= | Silent (SNP) | VAF 133/287 reads (46%) | catalogued as rs760790904; called by muse, mutect2, varscan2
- PCDH8 | c.963G>A p.E321= | Silent (SNP) | VAF 336/697 reads (48%) | called by muse, mutect2, varscan2
- PDE11A | c.2031C>T p.F677= | Silent (SNP) | VAF 120/248 reads (48%) | catalogued as rs777971390, COSV53700384; called by muse, mutect2, varscan2
- PHF2 | c.252T>C p.N84= | Silent (SNP) | VAF 169/384 reads (44%) | called by muse, mutect2, varscan2
- PITPNM2 | c.3192G>A p.G1064= | Silent (SNP) | VAF 236/484 reads (49%) | called by muse, mutect2, varscan2
- PROKR1 | c.1026C>T p.F342= | Silent (SNP) | VAF 207/422 reads (49%) | catalogued as COSV100375400; called by muse, varscan2
- PRSS35 | c.303A>G p.Q101= | Silent (SNP) | VAF 138/291 reads (47%) | catalogued as COSV63800053; called by muse, mutect2, varscan2
- PSMB5 | c.300G>A p.L100= | Silent (SNP) | VAF 155/317 reads (49%) | called by muse, mutect2, varscan2
- RC3H2 | c.840T>C p.H280= | Silent (SNP) | VAF 154/395 reads (39%) | catalogued as rs763280153; called by muse, mutect2, varscan2
- RFX1 | c.684G>A p.V228= | Silent (SNP) | VAF 218/471 reads (46%) | called by muse, mutect2, varscan2
- RHBG | c.360T>C p.H120= | Silent (SNP) | VAF 108/564 reads (19%) | called by muse, varscan2
- RNF213 | c.6321G>A p.P2107= | Silent (SNP) | VAF 184/364 reads (51%) | catalogued as rs777754815; called by muse, mutect2, varscan2
- RRNAD1 | c.108C>A p.I36= | Silent (SNP) | VAF 110/494 reads (22%) | called by muse, varscan2
- SBNO2 | c.4029G>A p.A1343= | Silent (SNP) | VAF 232/455 reads (51%) | catalogued as rs781014228, COSV62323195; called by muse, mutect2, varscan2
- SHANK2 | c.4527T>C p.T1509= | Silent (SNP) | VAF 214/414 reads (52%) | called by muse, mutect2, varscan2
- SLC9A3R1 | c.175C>T p.L59= | Silent (SNP) | VAF 214/464 reads (46%) | called by muse, varscan2
- SLF1 | c.1605G>A p.T535= | Silent (SNP) | VAF 113/231 reads (49%) | catalogued as rs774988916; called by muse, mutect2, varscan2
- SMC1B | c.543T>C p.D181= | Silent (SNP) | VAF 134/331 reads (40%) | called by muse, mutect2, varscan2
- SPATA18 | c.42A>G p.L14= | Silent (SNP) | VAF 155/377 reads (41%) | called by muse, mutect2, varscan2
- SRP72 | c.1800A>G p.K600= | Silent (SNP) | VAF 154/336 reads (46%) | catalogued as rs766240259; called by muse, varscan2
- STAB1 | c.1068C>T p.Y356= | Silent (SNP) | VAF 225/444 reads (51%) | catalogued as rs138924200; called by muse, mutect2, varscan2
- STRIP1 | c.2247C>T p.D749= | Silent (SNP) | VAF 115/255 reads (45%) | catalogued as rs370148796; called by muse, mutect2, varscan2
- SVEP1 | c.8523T>C p.N2841= | Silent (SNP) | VAF 189/440 reads (43%) | called by muse, mutect2, varscan2
- SVEP1 | c.5268T>C p.S1756= | Silent (SNP) | VAF 122/278 reads (44%) | called by muse, mutect2, varscan2
- TET2 | c.885C>A p.A295= | Silent (SNP) | VAF 179/412 reads (43%) | called by muse, mutect2, varscan2
- TFEC | c.822G>A p.E274= | Silent (SNP) | VAF 213/415 reads (51%) | called by muse, mutect2, varscan2
- TMEM125 | c.238C>T p.L80= | Silent (SNP) | VAF 220/448 reads (49%) | called by muse, varscan2
- TMEM249 | c.502C>T p.L168= | Silent (SNP) | VAF 15/496 reads (3%) | called by muse, mutect2
- TNRC6B | c.5448C>T p.S1816= (on ENST00000454349 / NM_001162501.2; = p.S1706= on NM_015088.3) | Silent (SNP) | VAF 149/312 reads (48%) | catalogued as rs752749800; called by muse, mutect2, varscan2
- TRBV20-1 | c.105C>T p.I35= | Silent (SNP) | VAF 243/473 reads (51%) | catalogued as rs780750911; called by muse, mutect2, varscan2
- TRIT1 | c.357G>A p.V119= | Silent (SNP) | VAF 127/248 reads (51%) | called by muse, mutect2, varscan2
- TTN | c.70905T>C p.T23635= (on ENST00000591111; = p.T16211= on NM_003319.4) | Silent (SNP) | VAF 16/494 reads (3%) | called by muse, mutect2
- UBE2L5 | c.81T>C p.V27= | Silent (SNP) | VAF 215/450 reads (48%) | called by muse, mutect2, varscan2
- UBE2O | c.228C>T p.F76= | Silent (SNP) | VAF 259/617 reads (42%) | called by muse, mutect2, varscan2
- UBR4 | c.15264C>T p.S5088= | Silent (SNP) | VAF 154/304 reads (51%) | catalogued as rs763127905, COSV64399181; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP36 | c.231T>C p.D77= | Silent (SNP) | VAF 113/253 reads (45%) | called by muse, mutect2, varscan2
- UVRAG | c.519T>C p.N173= | Silent (SNP) | VAF 120/280 reads (43%) | called by muse, mutect2
- WDFY4 | c.2764C>T p.L922= | Silent (SNP) | VAF 136/264 reads (52%) | called by muse, varscan2
- ZBTB32 | c.1044G>A p.A348= | Silent (SNP) | VAF 34/476 reads (7%) | catalogued as rs780001367, COSV99386209; called by muse, mutect2
- ZFYVE26 | c.1491C>A p.L497= | Silent (SNP) | VAF 145/320 reads (45%) | catalogued as COSV100720327; called by muse, mutect2, varscan2
- ZMAT4 | c.249A>G p.S83= | Silent (SNP) | VAF 232/490 reads (47%) | called by muse, mutect2, varscan2
- ZMYM2 | c.603A>G p.Q201= | Silent (SNP) | VAF 202/395 reads (51%) | catalogued as rs375228563; called by muse, mutect2, varscan2
- ZNF106 | c.2232A>G p.V744= | Silent (SNP) | VAF 22/402 reads (5%) | catalogued as rs1290203323; called by muse, mutect2
- ZNF33B | c.504C>T p.D168= | Silent (SNP) | VAF 152/308 reads (49%) | catalogued as rs370800363; called by muse, mutect2, varscan2
- ZNF546 | c.2019G>A p.T673= | Silent (SNP) | VAF 274/560 reads (49%) | catalogued as rs145425928; called by muse, mutect2, varscan2
- ZNF564 | c.1581T>C p.H527= | Silent (SNP) | VAF 179/350 reads (51%) | called by muse, mutect2
- ATXN8OS | n.499+1617del | Intron (DEL) | VAF 121/322 reads (38%) | catalogued as rs995471009; called by mutect2, pindel, varscan2
- CHST15 | c.*2102C>T | 3'UTR (SNP) | VAF 93/223 reads (42%) | catalogued as rs1457175897; called by muse, mutect2, varscan2
- CTBP2 | c.58+12337C>T | Intron (SNP) | VAF 226/490 reads (46%) | catalogued as rs923247180, COSV58345539; called by muse, mutect2, varscan2
- GPX4 | c.*164G>A | 3'UTR (SNP) | VAF 194/411 reads (47%) | catalogued as rs763243332; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+21727G>A | Intron (SNP) | VAF 130/291 reads (45%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-32850dup | Intron (INS) | VAF 118/257 reads (46%) | catalogued as rs149468188; called by mutect2, varscan2
- KDM2B | c.1048-3449T>A | Intron (SNP) | VAF 88/196 reads (45%) | called by mutect2, varscan2
- MARVELD3 | chr16:71640441 T>C | 3'Flank (SNP) | VAF 155/360 reads (43%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-663A>T | Intron (SNP) | VAF 343/656 reads (52%) | called by muse, mutect2, varscan2
- NTRK3 | c.2133+12636G>A | Intron (SNP) | VAF 131/280 reads (47%) | catalogued as rs757853638; called by muse, mutect2, varscan2
- PALLD | c.*73del | 3'UTR (DEL) | VAF 50/307 reads (16%) | called by mutect2, varscan2
- PLEKHB2 | c.533-2212C>T | Intron (SNP) | VAF 100/216 reads (46%) | catalogued as rs1017078070; called by muse, mutect2, varscan2
- PRDX6 | chr1:173476829 A>G | 5'Flank (SNP) | VAF 161/726 reads (22%) | called by muse, mutect2, varscan2
- RTN4RL2 | c.513+713A>G | Intron (SNP) | VAF 168/394 reads (43%) | called by muse, mutect2, varscan2
- SCNN1A | c.-105C>T | 5'UTR (SNP) | VAF 188/393 reads (48%) | catalogued as rs1003784925; called by muse, mutect2, varscan2
- SEPTIN9 | c.76+13144G>A | Intron (SNP) | VAF 16/594 reads (3%) | called by muse, mutect2
- SH2B2 | chr7:102283058 A>G | 5'Flank (SNP) | VAF 215/422 reads (51%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.-265A>G | 5'UTR (SNP) | VAF 93/196 reads (47%) | called by muse, mutect2, varscan2
- SLC39A1 | c.*831del | 3'UTR (DEL) | VAF 150/676 reads (22%) | called by pindel, varscan2
- SNX20 | chr16:50669142 ins C | 3'Flank (INS) | VAF 146/367 reads (40%) | called by mutect2, pindel, varscan2
- SYNPO | chr5:150656960 T>G | 3'Flank (SNP) | VAF 216/422 reads (51%) | called by muse, mutect2, varscan2
- UBR7 | c.*667T>C | 3'UTR (SNP) | VAF 26/342 reads (8%) | catalogued as rs1254755969; called by muse, mutect2
- UNC13B | c.761+5105C>T | Intron (SNP) | VAF 136/276 reads (49%) | called by muse, varscan2
- UNC13B | c.1168-14652A>G | Intron (SNP) | VAF 185/410 reads (45%) | called by muse, mutect2, varscan2
- WDR64 | c.-9T>C | 5'UTR (SNP) | VAF 149/707 reads (21%) | called by muse, mutect2, varscan2
